Somatic mutation profile of tumor specimen TCGA-22-5489-01A (aliquot TCGA-22-5489-01A-01D-1632-08) from TCGA case TCGA-22-5489, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 64.7 years (23,618 days).
Specimen TCGA-22-5489-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4e0a2a8c-80a1-43e1-a95c-c9a745163355.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-22-5489-11A (Solid Tissue Normal), aliquot TCGA-22-5489-11A-01D-1632-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fde9a035-8201-4c8c-bf4e-acdf9197211d

The open-access MAF lists 264 somatic variants for this specimen: 199 protein-altering or splice-affecting, 59 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 170, Silent 59, Nonsense Mutation 14, Splice Site 6, Frame Shift Del 6, RNA 3, Intron 2, Splice Region 2, Frame Shift Ins 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTEN | c.959T>A p.L320* | Nonsense Mutation (SNP) | VAF 26/116 reads (22%) | hotspot (GDC flag); catalogued as rs1114167667, CD110181, CM033671, CM1513166, CM992427, COSV64288766, COSV64288772, COSV64297208, COSV64305848; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.916C>T p.R306* | Nonsense Mutation (SNP) | VAF 17/72 reads (24%) | hotspot (GDC flag); catalogued as rs121913344, CM971506, COSV52662281, COSV52987117, COSV53852813; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ADORA1 | c.943A>G p.I315V | Missense Mutation (SNP) | VAF 26/88 reads (30%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as COSV55144128; called by muse, mutect2, varscan2
- AFAP1 | c.727-1G>A p.X243_splice | Splice Site (SNP) | VAF 11/28 reads (39%) | catalogued as COSV100632281, COSV61798641; called by muse, mutect2, varscan2
- ALPK2 | c.686G>T p.R229I | Missense Mutation (SNP) | VAF 50/218 reads (23%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV64496908; called by muse, mutect2, varscan2
- ALS2 | c.3836+1G>T p.X1279_splice | Splice Site (SNP) | VAF 9/63 reads (14%) | catalogued as CS1311298, COSV51892316; called by muse, mutect2
- ANKRD13B | c.241G>A p.G81S | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.647); catalogued as COSV67474425; called by muse, mutect2
- ANKRD20A4P | c.2040G>T p.K680N | Missense Mutation (SNP) | VAF 45/104 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.013); catalogued as COSV100628594; called by muse, mutect2, varscan2
- ANKRD34B | c.1465A>T p.K489* | Nonsense Mutation (SNP) | VAF 24/128 reads (19%) | catalogued as COSV58614480; called by muse, mutect2, varscan2
- ANKS1A | c.1570G>C p.G524R | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT tolerated (0.14); PolyPhen benign (0.186); catalogued as COSV64464467; called by muse, mutect2, varscan2
- ANKS1A | c.1571G>T p.G524V | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT deleterious (0.03); PolyPhen benign (0.245); catalogued as COSV64464474; called by muse, mutect2, varscan2
- ANO6 | c.2150A>G p.K717R | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT tolerated (0.42); PolyPhen benign (0.311); catalogued as COSV57667668; called by muse, mutect2, varscan2
- ARHGAP35 | c.585A>G p.I195M | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.129); catalogued as COSV68335518; called by muse, mutect2, varscan2
- ASB2 | c.292G>T p.A98S | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.979); catalogued as COSV60112158, COSV60114316; called by muse, mutect2, varscan2
- ATRN | c.480G>T p.W160C | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53534070; called by muse, mutect2, varscan2
- B3GNT3 | c.368G>A p.R123H | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs752385665, COSV59438987; called by muse, mutect2, varscan2
- BNC2 | c.2731G>T p.D911Y | Missense Mutation (SNP) | VAF 23/184 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.615); catalogued as COSV66175802; called by muse, mutect2, varscan2
- C7orf57 | c.383T>A p.V128D | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV62364123; called by muse, mutect2, varscan2
- CABS1 | c.581C>T p.S194F | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.104); catalogued as COSV56734507; called by muse, mutect2, varscan2
- CADPS2 | c.2737C>T p.R913* | Nonsense Mutation (SNP) | VAF 3/22 reads (14%) | catalogued as rs1430897622, COSV57355313; called by muse, mutect2
- CATSPERD | c.2365C>A p.R789S | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.009); catalogued as COSV58467446; called by muse, mutect2, varscan2
- CD1E | c.729G>A p.M243I | Missense Mutation (SNP) | VAF 44/98 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.401); catalogued as rs1225621935, COSV63771167; called by muse, mutect2, varscan2
- CDH19 | c.1475G>C p.S492T | Missense Mutation (SNP) | VAF 14/115 reads (12%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.687); catalogued as COSV50976103; called by muse, mutect2, varscan2
- CEP97 | c.847C>G p.Q283E | Missense Mutation (SNP) | VAF 16/81 reads (20%) | SIFT tolerated (0.38); PolyPhen benign (0.074); catalogued as COSV59127932; called by muse, mutect2, varscan2
- CFAP61 | c.2209G>A p.V737I | Missense Mutation (SNP) | VAF 26/145 reads (18%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.708); catalogued as rs1477276055, COSV55646623; called by muse, mutect2, varscan2
- CHRNB4 | c.667A>T p.T223S | Missense Mutation (SNP) | VAF 16/87 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.643); catalogued as COSV55718226; called by muse, mutect2, varscan2
- CLDN12 | c.544G>T p.A182S | Missense Mutation (SNP) | VAF 53/211 reads (25%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as COSV55308000; called by muse, mutect2, varscan2
- CNTN1 | c.1110G>T p.A370= | Splice Region (SNP) | VAF 28/136 reads (21%) | catalogued as COSV100751050; called by mutect2, varscan2
- COL11A1 | c.144C>A p.H48Q | Missense Mutation (SNP) | VAF 23/74 reads (31%) | SIFT tolerated (0.86); PolyPhen benign (0.001); catalogued as COSV62196603; called by muse, mutect2, varscan2
- COL2A1 | c.4057A>G p.I1353V | Missense Mutation (SNP) | VAF 54/211 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.029); catalogued as COSV61534062; called by muse, mutect2, varscan2
- CSMD2 | c.2467C>A p.H823N | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT tolerated (0.75); PolyPhen benign (0.232); catalogued as COSV53959588; called by muse, mutect2, varscan2
- CUBN | c.5791A>G p.T1931A | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT tolerated (0.72); PolyPhen benign (0.08); catalogued as COSV64726730; called by muse, mutect2, varscan2
- CUBN | c.3665A>G p.Y1222C | Missense Mutation (SNP) | VAF 22/101 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV64726735; called by muse, mutect2, varscan2
- DCC | c.80T>G p.L27R | Missense Mutation (SNP) | VAF 22/105 reads (21%) | SIFT tolerated (0.27); PolyPhen benign (0.036); catalogued as COSV71440292; called by muse, mutect2, varscan2
- DCC | c.3499A>G p.K1167E | Missense Mutation (SNP) | VAF 28/102 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV71440295; called by muse, mutect2, varscan2
- DCD | c.57C>T p.A19= | Splice Region (SNP) | VAF 4/36 reads (11%) | catalogued as COSV53202409; called by muse, mutect2
- DCHS1 | c.5071A>T p.S1691C | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as COSV55042396; called by muse, mutect2
- DCX | c.79C>A p.P27T | Missense Mutation (SNP) | VAF 32/75 reads (43%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.964); catalogued as COSV57575079; called by muse, mutect2, varscan2
- DEUP1 | c.423G>C p.Q141H | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.599); catalogued as COSV53216299, COSV53216438; called by muse, mutect2, varscan2
- DHX33 | c.1159G>C p.E387Q | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.897); catalogued as COSV56580831; called by muse, mutect2, varscan2
- DNAH7 | c.9674C>A p.P3225H | Missense Mutation (SNP) | VAF 20/66 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV56784753; called by muse, mutect2, varscan2
- DUSP5 | c.1009T>G p.S337A | Missense Mutation (SNP) | VAF 11/70 reads (16%) | SIFT tolerated (0.26); PolyPhen benign (0.055); catalogued as COSV63647277; called by muse, mutect2, varscan2
- DYNC1H1 | c.884C>A p.P295Q | Missense Mutation (SNP) | VAF 3/45 reads (7%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.825); catalogued as COSV100795135; called by muse, mutect2
- EGF | c.704G>A p.G235E | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54484397; called by muse, mutect2, varscan2
- ENTPD7 | c.688G>C p.G230R | Missense Mutation (SNP) | VAF 99/342 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65113229; called by muse, mutect2, varscan2
- EP400 | c.9086C>G p.S3029C | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.912); catalogued as COSV57785801; called by muse, mutect2, varscan2
- EPYC | c.166-1G>A p.X56_splice | Splice Site (SNP) | VAF 22/66 reads (33%) | catalogued as rs10859087, COSV53799330; called by mutect2, varscan2
- ERICH3 | c.2651C>T p.T884I | Missense Mutation (SNP) | VAF 101/274 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.053); catalogued as COSV58610034, COSV58617760; called by muse, mutect2, varscan2
- EYS | c.595A>G p.S199G | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT tolerated (0.23); PolyPhen benign (0.138); catalogued as COSV60999510; called by muse, mutect2, varscan2
- F2RL1 | c.568A>G p.I190V | Missense Mutation (SNP) | VAF 30/140 reads (21%) | SIFT tolerated (0.55); PolyPhen benign (0.018); catalogued as rs549819353, COSV56996825; called by muse, mutect2, varscan2
- FAM135B | c.855G>T p.Q285H | Missense Mutation (SNP) | VAF 44/105 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.671); catalogued as COSV52706687; called by muse, mutect2, varscan2
- FDPS | c.794A>T p.Y265F | Missense Mutation (SNP) | VAF 51/190 reads (27%) | SIFT tolerated (0.11); PolyPhen benign (0.345); catalogued as COSV63115358; called by muse, mutect2, varscan2
- FOXN2 | c.781C>T p.P261S | Missense Mutation (SNP) | VAF 17/60 reads (28%) | SIFT tolerated (0.1); PolyPhen benign (0.197); catalogued as COSV61319807; called by muse, mutect2, varscan2
- GAB4 | c.556C>A p.L186I | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.952); catalogued as COSV68755170; called by muse, mutect2, varscan2
- GABRB2 | c.293A>G p.Y98C | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV50942876; called by muse, mutect2, varscan2
- GALNTL6 | c.908C>A p.P303H | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV72493683, COSV72494816; called by muse, mutect2
- GALR1 | c.880A>T p.S294C | Missense Mutation (SNP) | VAF 23/104 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV55319025; called by muse, mutect2, varscan2
- GBP2 | c.1207G>C p.D403H | Missense Mutation (SNP) | VAF 48/128 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.153); catalogued as COSV65070400; called by muse, mutect2, varscan2
- GGTLC1 | c.463G>A p.V155M | Missense Mutation (SNP) | VAF 17/114 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.503); catalogued as rs755188208, COSV53846183; called by muse, mutect2, varscan2
- GLB1L3 | c.1262G>A p.W421* | Nonsense Mutation (SNP) | VAF 38/142 reads (27%) | catalogued as COSV68393064; called by muse, mutect2, varscan2
- GMIP | c.1501G>T p.G501C | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs749020673, COSV52559832; called by muse, mutect2, varscan2
- GNPTAB | c.1408+2T>C p.X470_splice | Splice Site (SNP) | VAF 16/53 reads (30%) | catalogued as COSV68449966; called by muse, mutect2, varscan2
- GOLM2 | c.992A>G p.D331G | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.133); catalogued as rs756174921, COSV55466342; called by muse, mutect2, varscan2
- GRIA4 | c.218C>A p.T73K | Missense Mutation (SNP) | VAF 6/81 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.309); catalogued as COSV56918351; called by muse, mutect2
- GRM5 | c.1390G>T p.G464* | Nonsense Mutation (SNP) | VAF 7/42 reads (17%) | catalogued as COSV59628156; called by muse, mutect2, varscan2
- HCN1 | c.378G>T p.R126S | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV57536033; called by muse, mutect2, varscan2
- HCN1 | c.377G>T p.R126M | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV57536042; called by muse, mutect2, varscan2
- HDHD5 | c.903G>T p.W301C (on ENST00000336737 / NM_033070.3; = p.W271C on NM_017829.5) | Missense Mutation (SNP) | VAF 31/178 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as COSV50093497; called by muse, mutect2, varscan2
- HIRIP3 | c.104C>G p.A35G | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); catalogued as COSV54231719; called by muse, mutect2, varscan2
- HMCN1 | c.4315A>T p.T1439S | Missense Mutation (SNP) | VAF 38/109 reads (35%) | SIFT tolerated (0.82); PolyPhen benign (0.033); catalogued as COSV54939416; called by muse, mutect2, varscan2
- HSPG2 | c.2330A>G p.Y777C | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.999); catalogued as COSV65977035; called by muse, mutect2, varscan2
- IL11RA | c.898G>C p.D300H | Missense Mutation (SNP) | VAF 7/68 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52405688; called by muse, mutect2
- IMPG1 | c.320G>T p.W107L | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64061578; called by muse, mutect2, varscan2
- INTS8 | c.926G>A p.C309Y | Missense Mutation (SNP) | VAF 10/214 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58253263; called by muse, mutect2
- IQCH | c.2906G>A p.R969H | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT tolerated (0.14); PolyPhen benign (0.071); catalogued as rs573462466, COSV60059631; called by muse, mutect2, varscan2
- KCNA5 | c.841C>A p.L281M | Missense Mutation (SNP) | VAF 69/123 reads (56%) | SIFT tolerated (0.1); PolyPhen benign (0.017); catalogued as COSV52908562; called by muse, mutect2, varscan2
- KIAA0513 | c.135T>G p.S45R | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV50744441; called by muse, mutect2, varscan2
- KLK2 | c.309G>C p.M103I | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT tolerated (0.42); PolyPhen benign (0.023); catalogued as COSV100320028, COSV57570827; called by muse, mutect2, varscan2
- KLRF1 | c.668G>T p.S223I | Missense Mutation (SNP) | VAF 33/66 reads (50%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.937); catalogued as rs758416219, COSV54382096; called by muse, mutect2, varscan2
- KRTAP10-8 | c.500T>C p.V167A | Missense Mutation (SNP) | VAF 49/242 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.222); catalogued as COSV58167256; called by muse, mutect2, varscan2
- LAMC1 | c.3682G>A p.E1228K | Missense Mutation (SNP) | VAF 40/110 reads (36%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as rs765549975, COSV51175376; called by muse, mutect2, varscan2
- LILRA2 | c.884G>T p.C295F | Missense Mutation (SNP) | VAF 25/79 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.682); catalogued as COSV52196533; called by muse, mutect2, varscan2
- LPAR4 | c.894C>A p.C298* | Nonsense Mutation (SNP) | VAF 19/50 reads (38%) | catalogued as COSV70913389; called by muse, mutect2, varscan2
- LRGUK | c.262G>C p.E88Q | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.806); catalogued as rs753816888, COSV53637618, COSV53643428; called by muse, mutect2, varscan2
- LRRC7 | c.4718T>C p.L1573P (on ENST00000651989 / NM_001370785.2; = p.L1493P on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 25/63 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs746947342, COSV50619060; called by muse, mutect2, varscan2
- LY9 | c.1193C>A p.P398Q | Missense Mutation (SNP) | VAF 23/65 reads (35%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.989); catalogued as rs150208343, COSV54437641; called by muse, mutect2, varscan2
- LYST | c.1864C>T p.Q622* | Nonsense Mutation (SNP) | VAF 37/142 reads (26%) | catalogued as COSV67713727; called by muse, varscan2
- MACC1 | c.1319G>T p.C440F | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.212); catalogued as COSV60546270; called by muse, mutect2, varscan2
- MADD | c.3770A>G p.H1257R | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT tolerated (0.15); PolyPhen benign (0.354); catalogued as COSV60629543; called by muse, mutect2, varscan2
- MICAL3 | c.3372G>T p.E1124D | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.01); catalogued as rs1465728206, COSV101490926; called by muse, mutect2
- MN1 | c.131C>G p.P44R | Missense Mutation (SNP) | VAF 11/86 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.074); catalogued as rs773038750, COSV56561821; called by mutect2, varscan2
- MROH2B | c.1415G>T p.S472I | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.264); catalogued as COSV68189254; called by muse, mutect2, varscan2
- MTNR1B | c.364C>A p.L122M | Missense Mutation (SNP) | VAF 24/112 reads (21%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.93); catalogued as COSV57068823; called by muse, mutect2, varscan2
- MUC3A | c.7349C>A p.S2450Y | Missense Mutation (SNP) | VAF 19/103 reads (18%) | SIFT deleterious, low confidence (0); catalogued as COSV60224319; called by muse, mutect2, varscan2
- MYH8 | c.664C>A p.Q222K | Missense Mutation (SNP) | VAF 18/87 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.554); catalogued as COSV67964458, COSV67972087, COSV67974244; called by muse, mutect2, varscan2
- NCAM2 | c.83G>C p.S28T | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT tolerated (0.35); PolyPhen benign (0.262); catalogued as COSV53102148; called by muse, mutect2, varscan2
- NEO1 | c.3699G>A p.M1233I | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.316); catalogued as rs1320323717, COSV56067826, COSV56077942; called by muse, mutect2
- NISCH | c.2360G>T p.S787I | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.896); catalogued as rs768739408, COSV61902119; called by muse, mutect2, varscan2
- NT5E | c.788A>T p.Y263F | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV57630255; called by muse, mutect2, varscan2
- NXPE3 | c.946C>T p.Q316* | Nonsense Mutation (SNP) | VAF 21/114 reads (18%) | catalogued as rs769964471, COSV56289984, COSV56292180; called by muse, mutect2, varscan2
- OR2H1 | c.522C>G p.D174E | Missense Mutation (SNP) | VAF 85/196 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.676); catalogued as COSV65811420; called by muse, mutect2, varscan2
- OR4K15 | c.1043A>T p.K348M (on ENST00000305051; = p.K324M on NM_001005486.1) | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.221); catalogued as COSV59303308; called by muse, mutect2
- OR52D1 | c.805C>G p.H269D | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.175); catalogued as COSV59488267; called by muse, mutect2, varscan2
- OR52N1 | c.898A>T p.R300W | Missense Mutation (SNP) | VAF 24/124 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.447); catalogued as COSV57694009; called by muse, mutect2, varscan2
- OR56A1 | c.469C>T p.L157F | Missense Mutation (SNP) | VAF 12/79 reads (15%) | SIFT tolerated (0.16); PolyPhen benign (0.019); catalogued as COSV57363875; called by muse, mutect2, varscan2
- OR56A1 | c.166G>C p.A56P | Missense Mutation (SNP) | VAF 12/73 reads (16%) | SIFT tolerated (0.52); PolyPhen benign (0.012); catalogued as COSV57363885; called by muse, mutect2, varscan2
- OR5B21 | c.367G>C p.A123P | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.557); catalogued as COSV64482267; called by muse, mutect2
- OR5K1 | c.44C>A p.T15K | Missense Mutation (SNP) | VAF 26/220 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.013); catalogued as COSV60305297; called by muse, mutect2, varscan2
- OR5R1 | c.301C>A p.L101M | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.98); catalogued as COSV56573604; called by muse, mutect2, varscan2
- OR5T3 | c.732G>T p.K244N | Missense Mutation (SNP) | VAF 38/228 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.21); catalogued as COSV100282860, COSV100282869; called by muse, mutect2, varscan2
- OR8J1 | c.409T>A p.S137T | Missense Mutation (SNP) | VAF 21/101 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.86); catalogued as COSV57320032, COSV57320433; called by muse, mutect2, varscan2
- PAPPA2 | c.5167G>T p.D1723Y | Missense Mutation (SNP) | VAF 34/152 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV62794188, COSV62810910; called by muse, mutect2, varscan2
- PASD1 | c.2302G>T p.D768Y | Missense Mutation (SNP) | VAF 17/40 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.74); catalogued as COSV64857594; called by muse, mutect2, varscan2
- PCDH19 | c.1352C>A p.P451Q | Missense Mutation (SNP) | VAF 23/53 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM162899, COSV55271064, COSV99721011; called by muse, mutect2, varscan2
- PCDHB10 | c.97T>A p.Y33N | Missense Mutation (SNP) | VAF 33/126 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV53383525; called by muse, mutect2, varscan2
- PDS5B | c.161A>T p.E54V | Missense Mutation (SNP) | VAF 38/128 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.669); catalogued as COSV59734249; called by muse, mutect2, varscan2
- PENK | c.541G>A p.E181K | Missense Mutation (SNP) | VAF 100/213 reads (47%) | SIFT deleterious (0.05); PolyPhen benign (0.282); catalogued as COSV59243102; called by muse, mutect2, varscan2
- PEX5L | c.770C>A p.S257Y | Missense Mutation (SNP) | VAF 15/95 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.804); catalogued as COSV55856829; called by muse, mutect2, varscan2
- PHACTR3 | c.671C>T p.S224F | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.133); catalogued as COSV63033933; called by muse, mutect2, varscan2
- PIK3CA | c.193G>A p.E65K | Missense Mutation (SNP) | VAF 17/162 reads (10%) | SIFT tolerated (0.74); PolyPhen possibly damaging (0.604); catalogued as rs766896653, COSV55992167; called by muse, mutect2, varscan2
- PKD2L2 | c.1372G>A p.G458S | Missense Mutation (SNP) | VAF 11/67 reads (16%) | SIFT tolerated (0.32); PolyPhen benign (0.012); catalogued as COSV51801480; called by muse, mutect2, varscan2
- PLVAP | c.973G>A p.V325M | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT tolerated (0.11); PolyPhen benign (0.042); catalogued as rs1252932417, COSV53087638; called by muse, mutect2, varscan2
- POMC | c.5C>A p.P2Q | Missense Mutation (SNP) | VAF 22/70 reads (31%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.393); catalogued as COSV53035645; called by muse, mutect2, varscan2
- PPFIA2 | c.2150C>G p.S717C | Missense Mutation (SNP) | VAF 22/115 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV61053247; called by muse, mutect2, varscan2
- PPM1B | c.472A>G p.R158G | Missense Mutation (SNP) | VAF 40/150 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.847); catalogued as COSV56769703; called by muse, mutect2, varscan2
- PRELP | c.111G>T p.R37S | Missense Mutation (SNP) | VAF 33/88 reads (38%) | SIFT tolerated, low confidence (0.75); PolyPhen benign (0.001); catalogued as COSV58117503; called by muse, mutect2, varscan2
- PRNP | c.434A>G p.Y145C | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT tolerated (0.17); PolyPhen benign (0.09); catalogued as COSV65174037; called by muse, mutect2, varscan2
- PSEN1 | c.481-1G>C p.X161_splice | Splice Site (SNP) | VAF 31/149 reads (21%) | catalogued as CP025174, COSV56196886; called by muse, mutect2, varscan2
- RBBP6 | c.4073A>G p.N1358S | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.01); catalogued as COSV60508341; called by muse, mutect2, varscan2
- RBM22 | c.1046A>T p.Y349F | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.899); catalogued as COSV52273068; called by muse, mutect2, varscan2
- RFC1 | c.976G>C p.E326Q | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as COSV62901043; called by muse, mutect2, varscan2
- RGS7 | c.904C>A p.P302T | Missense Mutation (SNP) | VAF 15/65 reads (23%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.85); catalogued as COSV58559922; called by muse, mutect2, varscan2
- RNF31 | c.2554G>T p.D852Y | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60728610; called by muse, mutect2, varscan2
- RPL28 | c.236G>T p.R79L | Missense Mutation (SNP) | VAF 55/146 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.332); catalogued as COSV59805561, COSV59805813; called by muse, mutect2, varscan2
- RPL7 | c.522G>C p.L174F | Missense Mutation (SNP) | VAF 33/68 reads (49%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.872); catalogued as COSV53584278; called by muse, mutect2, varscan2
- RSL1D1 | c.985A>G p.T329A | Missense Mutation (SNP) | VAF 34/218 reads (16%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as COSV63078491; called by muse, mutect2, varscan2
- RYR3 | c.11954C>A p.P3985Q (on ENST00000389232; = p.P3986Q on NM_001036.6) | Missense Mutation (SNP) | VAF 21/109 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66807679; called by muse, mutect2, varscan2
- SETD1A | c.115G>A p.V39M | Missense Mutation (SNP) | VAF 8/103 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as COSV52692225; called by muse, mutect2
- SH3BGR | c.211G>T p.A71S | Missense Mutation (SNP) | VAF 46/208 reads (22%) | SIFT tolerated (0.17); PolyPhen benign (0.247); catalogued as COSV61324475; called by muse, mutect2, varscan2
- SIGLEC10 | c.193A>T p.T65S | Missense Mutation (SNP) | VAF 17/65 reads (26%) | SIFT tolerated (0.1); PolyPhen benign (0.038); catalogued as COSV59486403; called by muse, mutect2, varscan2
- SLC12A3 | c.500G>T p.G167V | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52638841; called by muse, varscan2
- SLC26A3 | c.233T>C p.V78A | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as rs1402332826, COSV60642577; called by muse, mutect2, varscan2
- SMG6 | c.2026G>A p.E676K | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT tolerated (0.63); PolyPhen benign (0.136); catalogued as COSV99558474; called by muse, mutect2, varscan2
- SNRNP200 | c.4696C>T p.R1566C | Missense Mutation (SNP) | VAF 11/147 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs943615586, COSV60494332; called by muse, mutect2
- SNX33 | c.1290G>T p.M430I | Missense Mutation (SNP) | VAF 29/96 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.039); catalogued as COSV57914529; called by muse, mutect2, varscan2
- SORCS1 | c.3074T>C p.L1025P | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.862); catalogued as COSV53903449, COSV53916441; called by muse, mutect2, varscan2
- SPEG | c.4849C>A p.R1617S | Missense Mutation (SNP) | VAF 27/131 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV56679241; called by muse, mutect2, varscan2
- SPTBN2 | c.17C>T p.S6L | Missense Mutation (SNP) | VAF 15/98 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.387); catalogued as COSV59460916; called by muse, mutect2, varscan2
- SREBF2 | c.106A>G p.S36G | Missense Mutation (SNP) | VAF 33/185 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.675); catalogued as COSV63332567; called by muse, mutect2, varscan2
- SRRM2 | c.3208G>C p.D1070H | Missense Mutation (SNP) | VAF 18/106 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.326); catalogued as rs1198285223, COSV57080190; called by muse, mutect2, varscan2
- STK4 | c.598G>T p.G200* | Nonsense Mutation (SNP) | VAF 15/89 reads (17%) | catalogued as COSV65671991; called by muse, mutect2, varscan2
- SYTL2 | c.1324G>T p.E442* | Nonsense Mutation (SNP) | VAF 22/165 reads (13%) | catalogued as COSV60363483; called by muse, mutect2, varscan2
- TAC1 | c.37G>C p.V13L | Missense Mutation (SNP) | VAF 17/130 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as COSV59988207; called by muse, mutect2, varscan2
- TAF1L | c.2029G>C p.G677R | Missense Mutation (SNP) | VAF 56/115 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54268737; called by muse, mutect2, varscan2
- TAOK2 | c.2474G>T p.S825I | Missense Mutation (SNP) | VAF 12/73 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as COSV54240700; called by muse, mutect2, varscan2
- TEKT4 | c.1157C>A p.A386E | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs112631866, COSV54622980, COSV54628330; called by muse, mutect2
- TFDP2 | c.1010C>T p.A337V (on ENST00000489671 / NM_001178139.2; = p.A277V on NM_006286.5) | Missense Mutation (SNP) | VAF 38/224 reads (17%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.997); catalogued as rs776411928, COSV57705762; called by muse, mutect2, varscan2
- TLR7 | c.1507A>T p.N503Y | Missense Mutation (SNP) | VAF 40/117 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66125518; called by muse, mutect2, varscan2
- TMEM175 | c.1201C>G p.Q401E | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV53281163; called by muse, mutect2, varscan2
- TMEM74B | c.637G>A p.G213S | Missense Mutation (SNP) | VAF 13/72 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.013); catalogued as rs375435487; called by muse, mutect2, varscan2
- TMX4 | c.851A>T p.N284I | Missense Mutation (SNP) | VAF 18/85 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.3); catalogued as rs756368624, COSV55682478; called by muse, mutect2, varscan2
- TRPC5 | c.465C>A p.Y155* | Nonsense Mutation (SNP) | VAF 11/32 reads (34%) | catalogued as COSV53302390; called by muse, mutect2, varscan2
- TRPM7 | c.1933G>T p.G645C | Missense Mutation (SNP) | VAF 26/116 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); catalogued as COSV57921357; called by muse, mutect2, varscan2
- TRPM8 | c.869T>A p.I290N | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT tolerated (0.39); PolyPhen benign (0.015); catalogued as COSV61224116; called by muse, mutect2, varscan2
- TTN | c.26786G>A p.R8929K (on ENST00000591111; = p.R8002K on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 23/74 reads (31%) | PolyPhen possibly damaging (0.875); catalogued as rs1404441295, COSV60331903; called by muse, mutect2, varscan2
- TTN | c.8113G>T p.E2705* (on ENST00000591111; = p.E2659* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 23/90 reads (26%) | catalogued as COSV60331979; called by muse, mutect2, varscan2
- TUBA3D | c.578C>A p.T193K | Missense Mutation (SNP) | VAF 54/257 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.784); catalogued as COSV58313259; called by muse, mutect2, varscan2
- TXNRD2 | c.1416A>C p.E472D | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV68693306; called by muse, mutect2, varscan2
- USP32 | c.3699C>G p.I1233M | Missense Mutation (SNP) | VAF 15/65 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV56277110; called by muse, mutect2, varscan2
- VCPIP1 | c.2866G>C p.E956Q | Missense Mutation (SNP) | VAF 55/102 reads (54%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.616); catalogued as COSV60050114; called by muse, mutect2, varscan2
- VPS13C | c.565C>G p.Q189E (on ENST00000644861 / NM_020821.3; = p.Q146E on NM_017684.5) | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV51423353; called by muse, mutect2, varscan2
- WDHD1 | c.1225C>G p.H409D | Missense Mutation (SNP) | VAF 19/89 reads (21%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as COSV62215616; called by muse, mutect2, varscan2
- WDPCP | c.1180G>T p.V394F | Missense Mutation (SNP) | VAF 33/127 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV55432214; called by muse, mutect2, varscan2
- WDR49 | c.1765A>G p.R589G (on ENST00000308378 / NM_001366158.1; = p.R930G on NM_001348951.2 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 6/82 reads (7%) | SIFT tolerated (0.41); PolyPhen benign (0.045); catalogued as COSV57705875, COSV57717411; called by muse, mutect2
- XPO7 | c.1639G>A p.E547K | Missense Mutation (SNP) | VAF 89/179 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV53020242; called by muse, mutect2, varscan2
- ZBTB20 | c.769G>A p.G257S (on ENST00000474710 / NM_001164342.2; = p.G184S on NM_015642.6 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 10/85 reads (12%) | SIFT tolerated (0.17); PolyPhen benign (0.369); catalogued as rs1330816881, COSV61857529; called by muse, varscan2
- ZEB2 | c.1309C>A p.Q437K | Missense Mutation (SNP) | VAF 41/105 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.248); catalogued as rs760437173, COSV57965837; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ZFHX4 | c.8375G>T p.G2792V | Missense Mutation (SNP) | VAF 19/43 reads (44%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.79); catalogued as COSV51494727; called by muse, mutect2, varscan2
- ZFYVE9 | c.2089G>A p.V697I | Missense Mutation (SNP) | VAF 32/64 reads (50%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.968); catalogued as rs1286133675, COSV55099953; called by muse, mutect2, varscan2
- ZNF235 | c.1119G>C p.K373N | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52158400; called by muse, mutect2, varscan2
- ZNF280A | c.939G>T p.M313I | Missense Mutation (SNP) | VAF 22/113 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.671); catalogued as rs1262769452, COSV57479672; called by muse, mutect2, varscan2
- ZNF415 | c.1193G>T p.S398I | Missense Mutation (SNP) | VAF 17/71 reads (24%) | SIFT tolerated (0.28); PolyPhen benign (0.013); catalogued as COSV54704944; called by muse, mutect2, varscan2
- ZNF467 | c.140G>T p.G47V | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.011); catalogued as COSV100118035; called by muse, mutect2, varscan2
- ZNF512 | c.503G>T p.S168I | Missense Mutation (SNP) | VAF 34/110 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.36); catalogued as COSV62673671, COSV62678196; called by muse, mutect2, varscan2
- ZNF534 | c.739C>G p.R247G (on ENST00000332323 / NM_001143939.3; = p.R234G on NM_001143938.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/64 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.027); catalogued as COSV56520786; called by muse, mutect2, varscan2
- ZNF676 | c.797T>A p.F266Y (on ENST00000650058; = p.F234Y on NM_001001411.3) | Missense Mutation (SNP) | VAF 20/143 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.094); catalogued as COSV68094850; called by muse, varscan2
- ZNF831 | c.4028-1G>T p.X1343_splice | Splice Site (SNP) | VAF 12/35 reads (34%) | catalogued as COSV64045003; called by muse, mutect2, varscan2
- ABCB5 | c.317T>A p.L106* | Nonsense Mutation (SNP) | VAF 4/22 reads (18%) | called by muse, mutect2
- AMER3 | c.1531T>A p.W511R | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by mutect2, varscan2
- HEATR6 | c.3419del p.G1140Afs*19 | Frame Shift Del (DEL) | VAF 12/84 reads (14%) | called by mutect2, pindel, varscan2
- IGDCC3 | c.235G>T p.G79W | Missense Mutation (SNP) | VAF 3/30 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- KANSL1L | c.2050_2051dup p.W684Cfs*14 | Frame Shift Ins (INS) | VAF 32/200 reads (16%) | called by mutect2, pindel, varscan2
- MAGEB6B | c.916G>C p.E306Q | Missense Mutation (SNP) | VAF 39/83 reads (47%) | SIFT deleterious (0.05); PolyPhen benign (0.165); called by muse, mutect2, varscan2
- NCKAP1L | c.2771del p.G924Dfs*20 | Frame Shift Del (DEL) | VAF 14/62 reads (23%) | called by mutect2, pindel, varscan2
- NIM1K | c.119del p.G40Dfs*6 | Frame Shift Del (DEL) | VAF 13/92 reads (14%) | called by mutect2, pindel, varscan2
- RXFP1 | c.1377_1392del p.F459Lfs*3 | Frame Shift Del (DEL) | VAF 17/97 reads (18%) | called by mutect2, pindel, varscan2
- TMC2 | c.630del p.M211Cfs*2 | Frame Shift Del (DEL) | VAF 10/40 reads (25%) | called by mutect2, pindel, varscan2
- WASHC2A | c.2792G>T p.W931L | Missense Mutation (SNP) | VAF 10/104 reads (10%) | SIFT tolerated (0.9); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ZDHHC21 | c.514del p.V172Ffs*8 | Frame Shift Del (DEL) | VAF 25/137 reads (18%) | called by pindel, varscan2
- ARAP1 | c.720G>T p.G240= | Silent (SNP) | VAF 11/69 reads (16%) | catalogued as COSV61992154, COSV61994847; called by muse, mutect2, varscan2
- ARMC3 | c.2190G>T p.V730= | Silent (SNP) | VAF 24/97 reads (25%) | catalogued as COSV53067436; called by muse, mutect2, varscan2
- ASTN1 | c.2193T>A p.G731= | Silent (SNP) | VAF 38/199 reads (19%) | catalogued as COSV56084240; called by muse, mutect2, varscan2
- B3GNT5 | c.1008T>C p.A336= | Silent (SNP) | VAF 46/91 reads (51%) | catalogued as COSV58476960; called by muse, mutect2, varscan2
- BDKRB2 | c.579G>T p.L193= | Silent (SNP) | VAF 14/78 reads (18%) | catalogued as COSV60015671, COSV60016922; called by muse, varscan2
- BSN | c.2535G>T p.R845= | Silent (SNP) | VAF 6/27 reads (22%) | catalogued as COSV56526891; called by muse, mutect2, varscan2
- CDH6 | c.753C>A p.T251= | Silent (SNP) | VAF 19/73 reads (26%) | catalogued as COSV54064957, COSV54077903; called by muse, mutect2, varscan2
- DIRAS3 | c.207C>T p.T69= | Silent (SNP) | VAF 24/134 reads (18%) | catalogued as rs554165010, COSV63971194; called by muse, varscan2
- DPAGT1 | c.261T>C p.C87= | Silent (SNP) | VAF 18/67 reads (27%) | catalogued as COSV62615147; called by muse, mutect2, varscan2
- DPH2 | c.1227C>T p.D409= | Silent (SNP) | VAF 9/80 reads (11%) | catalogued as rs770900701, COSV52545288; called by muse, mutect2, varscan2
- EPB41L4B | c.2460T>C p.D820= | Silent (SNP) | VAF 56/144 reads (39%) | catalogued as COSV65805018; called by muse, mutect2, varscan2
- ERP27 | c.669A>G p.A223= | Silent (SNP) | VAF 12/117 reads (10%) | catalogued as COSV56764766; called by muse, mutect2
- FCRL5 | c.768G>T p.G256= | Silent (SNP) | VAF 77/244 reads (32%) | catalogued as rs1178540908, COSV62519900; called by muse, mutect2, varscan2
- GK2 | c.27G>T p.V9= | Silent (SNP) | VAF 13/44 reads (30%) | catalogued as COSV62628317; called by muse, mutect2, varscan2
- GLRA3 | c.1215C>T p.H405= | Silent (SNP) | VAF 29/85 reads (34%) | catalogued as COSV56869760; called by muse, mutect2, varscan2
- H3C7 | c.147C>T p.L49= | Silent (SNP) | VAF 14/134 reads (10%) | catalogued as rs1199564873, COSV55100902; called by muse, mutect2, varscan2
- IGHV5-51 | c.285C>T p.I95= | Silent (SNP) | VAF 19/77 reads (25%) | called by muse, mutect2, varscan2
- IGSF9 | c.1209C>T p.T403= (on ENST00000368094 / NM_001135050.2; = p.T387= on NM_020789.4) | Silent (SNP) | VAF 26/82 reads (32%) | catalogued as rs532766563, COSV63639105; called by muse, mutect2, varscan2
- ITGB3 | c.1236T>C p.C412= | Silent (SNP) | VAF 12/100 reads (12%) | catalogued as COSV71385213; called by muse, mutect2, varscan2
- KIF2B | c.1083G>A p.G361= | Silent (SNP) | VAF 10/88 reads (11%) | catalogued as COSV52129616; called by muse, mutect2, varscan2
- KRTAP6-3 | c.150C>G p.G50= | Silent (SNP) | VAF 6/27 reads (22%) | catalogued as COSV66963375; called by muse, mutect2, varscan2
- LARP4B | c.1299A>G p.E433= | Silent (SNP) | VAF 40/148 reads (27%) | catalogued as COSV60223868; called by muse, mutect2, varscan2
- LRFN5 | c.1941T>A p.T647= | Silent (SNP) | VAF 6/28 reads (21%) | catalogued as rs1045836117, COSV53274092; called by muse, mutect2, varscan2
- LRRC8A | c.687G>T p.T229= | Silent (SNP) | VAF 11/30 reads (37%) | catalogued as rs376295105, COSV52189141; called by muse, mutect2, varscan2
- LYST | c.1788C>G p.L596= | Silent (SNP) | VAF 46/175 reads (26%) | catalogued as rs148614675, COSV67704335; called by muse, varscan2
- MACF1 | c.3789C>T p.L1263= | Silent (SNP) | VAF 8/48 reads (17%) | catalogued as rs1388375831, COSV58400895; called by muse, mutect2
- MAP3K1 | c.1072C>T p.L358= | Silent (SNP) | VAF 19/97 reads (20%) | catalogued as COSV68127260, COSV99064079; called by muse, mutect2, varscan2
- MAP3K19 | c.1260T>A p.V420= | Silent (SNP) | VAF 25/118 reads (21%) | catalogued as COSV59642071; called by muse, mutect2, varscan2
- MYH11 | c.2319C>G p.G773= | Silent (SNP) | VAF 17/78 reads (22%) | catalogued as COSV55557530, COSV55568949; called by muse, mutect2, varscan2
- NEBL | c.408C>T p.F136= | Silent (SNP) | VAF 15/92 reads (16%) | catalogued as COSV65800183; called by muse, mutect2, varscan2
- NID1 | c.1782C>T p.P594= | Silent (SNP) | VAF 21/82 reads (26%) | catalogued as rs201146842, COSV51616270; called by muse, mutect2, varscan2
- NOC3L | c.66C>T p.V22= | Silent (SNP) | VAF 22/82 reads (27%) | catalogued as COSV64930578; called by muse, mutect2, varscan2
- NSMCE1 | c.555C>T p.P185= | Silent (SNP) | VAF 17/99 reads (17%) | catalogued as rs375663140; called by muse, mutect2
- NTSR1 | c.219C>T p.L73= | Silent (SNP) | VAF 4/26 reads (15%) | catalogued as rs1007004263, COSV65139558; called by muse, mutect2
- OR5AP2 | c.183C>T p.L61= | Silent (SNP) | VAF 8/53 reads (15%) | catalogued as COSV57258256, COSV57258965; called by muse, mutect2, varscan2
- OR8A1 | c.834C>A p.T278= | Silent (SNP) | VAF 8/43 reads (19%) | catalogued as COSV52510338; called by muse, mutect2, varscan2
- PARP4 | c.3888A>C p.T1296= | Silent (SNP) | VAF 29/93 reads (31%) | catalogued as COSV67964107; called by muse, mutect2, varscan2
- PGBD4 | c.1290A>T p.A430= | Silent (SNP) | VAF 11/70 reads (16%) | catalogued as COSV56629157; called by muse, mutect2, varscan2
- PLBD1 | c.1297C>A p.R433= | Silent (SNP) | VAF 76/148 reads (51%) | catalogued as COSV53693861; called by muse, mutect2, varscan2
- PLXNC1 | c.1464A>G p.V488= | Silent (SNP) | VAF 43/206 reads (21%) | catalogued as COSV51574261; called by muse, mutect2, varscan2
- PRRC2C | c.2838A>G p.A946= (on ENST00000367742; = p.A944= on NM_015172.4) | Silent (SNP) | VAF 5/31 reads (16%) | catalogued as COSV58912708; called by muse, mutect2, varscan2
- PSMD1 | c.1866T>C p.L622= | Silent (SNP) | VAF 11/70 reads (16%) | catalogued as COSV58083348; called by muse, mutect2, varscan2
- RASGRF1 | c.2013C>G p.L671= | Silent (SNP) | VAF 13/84 reads (15%) | catalogued as COSV67251176; called by muse, mutect2, varscan2
- SCAF11 | c.3261T>C p.F1087= | Silent (SNP) | VAF 12/92 reads (13%) | catalogued as COSV65478989; called by muse, mutect2
- SCG3 | c.1266T>C p.H422= | Silent (SNP) | VAF 13/84 reads (15%) | catalogued as COSV55023181; called by muse, mutect2, varscan2
- SCLT1 | c.1359C>T p.F453= | Silent (SNP) | VAF 10/47 reads (21%) | catalogued as COSV55412388; called by muse, mutect2, varscan2
- SIGLEC8 | c.963G>A p.R321= | Silent (SNP) | VAF 10/58 reads (17%) | catalogued as COSV58475774; called by muse, mutect2, varscan2
- SIPA1L1 | c.1605C>T p.Y535= | Silent (SNP) | VAF 9/57 reads (16%) | catalogued as COSV62173446; called by muse, mutect2, varscan2
- SLC5A4 | c.1233C>T p.T411= | Silent (SNP) | VAF 26/103 reads (25%) | catalogued as COSV56669990; called by muse, mutect2, varscan2
- SLC6A16 | c.537C>T p.A179= | Silent (SNP) | VAF 4/30 reads (13%) | catalogued as rs751973976, COSV60030306; called by muse, mutect2
- SPINK7 | c.123G>A p.V41= | Silent (SNP) | VAF 22/155 reads (14%) | catalogued as COSV51001866; called by muse, mutect2, varscan2
- STAB1 | c.1185C>G p.G395= | Silent (SNP) | VAF 9/50 reads (18%) | catalogued as COSV58742722; called by muse, mutect2, varscan2
- TEKT4 | c.690G>A p.P230= | Silent (SNP) | VAF 18/59 reads (31%) | catalogued as rs149873671; called by mutect2, varscan2
- THEMIS2 | c.1287T>C p.S429= | Silent (SNP) | VAF 24/48 reads (50%) | catalogued as COSV61078419; called by muse, mutect2, varscan2
- TTN | c.10086C>A p.A3362= (on ENST00000591111; = p.A3316= on NM_003319.4) | Silent (SNP) | VAF 15/98 reads (15%) | catalogued as COSV60331922; called by muse, mutect2, varscan2
- TTYH2 | c.294C>T p.L98= | Silent (SNP) | VAF 11/46 reads (24%) | catalogued as rs766941560, COSV53913278; called by muse, mutect2, varscan2
- TUBGCP5 | c.1935G>C p.L645= | Silent (SNP) | VAF 28/111 reads (25%) | called by muse, mutect2, varscan2
- YWHAE | c.366T>C p.Y122= | Silent (SNP) | VAF 10/35 reads (29%) | catalogued as rs779406770, COSV51985267; called by muse, mutect2, varscan2
- ZNF770 | c.177G>A p.V59= | Silent (SNP) | VAF 10/88 reads (11%) | catalogued as COSV62545018; called by muse, mutect2
- ATP6AP1L | n.1566G>T | RNA (SNP) | VAF 39/182 reads (21%) | catalogued as COSV66475219, COSV66475585; called by muse, mutect2, varscan2
- CPSF6 | c.*3687A>C | 3'UTR (SNP) | VAF 15/74 reads (20%) | catalogued as COSV57018423; called by muse, mutect2, varscan2
- MIR663B | n.32G>T | RNA (SNP) | VAF 4/17 reads (24%) | called by muse, mutect2, varscan2
- NBPF7 | n.456C>G | RNA (SNP) | VAF 37/125 reads (30%) | called by muse, mutect2, varscan2
- NCAM1 | c.1826-5570G>T | Intron (SNP) | VAF 34/217 reads (16%) | catalogued as COSV100377821; called by muse, mutect2, varscan2
- TTN | c.34264+5491T>G | Intron (SNP) | VAF 8/54 reads (15%) | catalogued as COSV60331895; called by muse, mutect2, varscan2
